Somatic mutation profile of tumor specimen TCGA-D3-A3C1-06A (aliquot TCGA-D3-A3C1-06A-12D-A196-08) from TCGA case TCGA-D3-A3C1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D3-A3C1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efd5d527-2b89-4e72-9989-c9e5d8b99f80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3C1-10A (Blood Derived Normal), aliquot TCGA-D3-A3C1-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c4e6f4c-b86b-4e1d-a724-18ac5385bfa7

The open-access MAF lists 162 somatic variants for this specimen: 115 protein-altering or splice-affecting, 45 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 45, Nonsense Mutation 9, Splice Region 3, Frame Shift Del 2, Frame Shift Ins 2, Nonstop Mutation 1, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/132 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AAAS | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 124/188 reads (66%) | catalogued as rs145446970, CM010151; called by muse, varscan2
- ADGRG4 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54962282; called by muse, mutect2, varscan2
- AHCTF1 | c.1186C>T p.R396* (on ENST00000366508; = p.R370* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 26/134 reads (19%) | catalogued as COSV58248386; called by muse, mutect2, varscan2
- AMDHD1 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 152/263 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764758506, COSV57139631; called by muse, mutect2, varscan2
- ANGPT1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV52448902; called by muse, mutect2, varscan2
- ARFGEF2 | c.4897G>A p.E1633K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV64212205; called by muse, mutect2, varscan2
- ARHGEF12 | c.3033G>A p.R1011= | Splice Region (SNP) | VAF 23/129 reads (18%) | catalogued as COSV63106246; called by muse, mutect2, varscan2
- ATP8A1 | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52542022; called by muse, mutect2, varscan2
- CBX7 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs546793926, COSV53359494; called by muse, mutect2, varscan2
- CD63 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 100/184 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs144910349, COSV57676923; called by muse, varscan2
- CD63 | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1299540378, COSV57676933; called by muse, varscan2
- CERKL | c.859C>T p.P287S (on ENST00000339098 / NM_001030311.2; = p.P261S on NM_201548.5) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV59209168, COSV59210950; called by muse, mutect2, varscan2
- CLCN3 | c.530A>T p.N177I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV61627957; called by muse, mutect2, varscan2
- CLDN4 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV52896638; called by muse, mutect2, varscan2
- CNNM1 | c.1611T>G p.N537K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV63202810; called by muse, mutect2, varscan2
- CNOT4 | c.1127C>T p.S376L (on ENST00000315544 / NM_001190848.1; = p.S373L on NM_013316.4) | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV59655891; called by muse, mutect2, varscan2
- CNTN6 | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610451, COSV63181477; called by muse, mutect2, varscan2
- COBLL1 | c.932C>T p.S311F (on ENST00000392717; = p.S273F on NM_014900.5) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1056185268, COSV52072279; called by muse, mutect2, varscan2
- CR2 | c.2113G>T p.G705* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | catalogued as COSV65508752, COSV65509815; called by muse, mutect2, varscan2
- CRACD | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs749262656, COSV51726851; called by muse, mutect2, varscan2
- CRTAM | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs1467824849, COSV57069745; called by muse, mutect2
- CSMD3 | c.1612G>A p.D538N (on ENST00000297405 / NM_001363185.1; = p.D434N on NM_052900.3) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52252722, COSV99847716; called by muse, mutect2, varscan2
- CTNND2 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs756966820, COSV58908222; called by muse, mutect2, varscan2
- DAGLA | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1190966234, COSV57198129; called by muse, mutect2, varscan2
- DDIT4L | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs1426364700, COSV56767243; called by muse, mutect2, varscan2
- DEFB114 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59038296; called by muse, mutect2, varscan2
- DNAH7 | c.5713G>A p.V1905I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.146); catalogued as COSV56775635; called by muse, mutect2
- DNAJC12 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs376515623; called by muse, mutect2, varscan2
- DSCAM | c.5455G>A p.E1819K | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68030907; called by muse, mutect2, varscan2
- DSCAML1 | c.5984G>A p.R1995Q (on ENST00000321322; = p.R1935Q on NM_020693.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.65); catalogued as rs764639033, COSV58397336; called by muse, mutect2, varscan2
- DSG4 | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); catalogued as COSV100356036, COSV57394701; called by muse, mutect2, varscan2
- EIF4G3 | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51688428; called by muse, mutect2, varscan2
- FLG | c.6524G>A p.G2175E | Missense Mutation (SNP) | VAF 157/406 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1180298519, COSV100910918, COSV64245100; called by muse, mutect2, varscan2
- FLG2 | c.5011G>A p.G1671R | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as COSV66171005; called by muse, mutect2, varscan2
- FLT1 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56735152; called by muse, mutect2, varscan2
- FN1 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as COSV60558873; called by muse, mutect2, varscan2
- GALNT9 | c.1597C>T p.R533C (on ENST00000328957 / NM_001122636.2; = p.R167C on NM_021808.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs773016379, COSV61101430; called by muse, mutect2, varscan2
- GIMAP7 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 91/127 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57960007; called by muse, mutect2, varscan2
- HEPH | c.2263G>A p.E755K (on ENST00000343002; = p.E488K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV57968229; called by muse, mutect2, varscan2
- HOXB3 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779723257, COSV61143791, COSV61144481; called by muse, mutect2, varscan2
- HSPG2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs142248704; called by muse, mutect2, varscan2
- HUNK | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213782034, COSV54231687; called by muse, mutect2, varscan2
- INHBB | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs761406590, COSV54678741; called by muse, mutect2, varscan2
- IQCF1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 156/459 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs781591419, COSV58823787; called by muse, mutect2, varscan2
- KAT14 | c.381C>A p.V127= | Splice Region (SNP) | VAF 57/216 reads (26%) | catalogued as COSV66608561; called by muse, mutect2, varscan2
- KBTBD8 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.971); catalogued as rs534443174, COSV55130319; called by muse, mutect2, varscan2
- KCNH2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV51211511; called by muse, mutect2
- KNG1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV53979625; called by muse, mutect2, varscan2
- KRT6C | c.1126A>G p.N376D | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV52879043; called by muse, mutect2, varscan2
- LAMA1 | c.3182G>A p.G1061D | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746226346, COSV67540615; called by muse, mutect2, varscan2
- LIFR | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs373421600; called by muse, mutect2, varscan2
- LILRB2 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58747110; called by muse, mutect2, varscan2
- MBD5 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV68697479; called by muse, mutect2, varscan2
- MUC16 | c.16900C>A p.L5634M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.024); catalogued as COSV67480258; called by muse, mutect2
- MVP | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762222128, COSV62422850; called by muse, mutect2, varscan2
- MYBPC3 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57031315; called by muse, mutect2, varscan2
- MYH15 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV56315407; called by muse, mutect2, varscan2
- NVL | c.2457T>G p.G819= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as COSV55874493; called by muse, mutect2, varscan2
- OR11L1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.877); catalogued as rs1416215176, COSV63315109; called by muse, mutect2, varscan2
- OR14K1 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV99314997; called by muse, mutect2, varscan2
- OR2L13 | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV63557351; called by muse, mutect2, varscan2
- OR4A15 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV59036263; called by muse, mutect2, varscan2
- OSBPL11 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56175377; called by muse, mutect2, varscan2
- PCDHB16 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.009); catalogued as COSV53367127; called by muse, mutect2, varscan2
- PCDHGC4 | c.1043C>G p.P348R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52759368; called by muse, mutect2, varscan2
- PMFBP1 | c.2222G>A p.R741Q (on ENST00000537465; = p.R736Q on NM_031293.3) | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs550070785, COSV52822956; called by muse, mutect2, varscan2
- PODXL2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs114228905, COSV61066041; called by muse, mutect2, varscan2
- PPP4R2 | c.1253A>T p.*418Lext*6 | Nonstop Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs1324273979, COSV99865780; called by muse, mutect2
- PROS1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs747259055, CM142190, COSV67776384; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1762G>A p.E588K (on ENST00000352766; = p.E509K on NM_181334.5) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as rs1295086078, COSV61235454; called by muse, mutect2
- PTPRT | c.1001G>A p.W334* | Nonsense Mutation (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100626118, COSV61966932; called by muse, mutect2, varscan2
- RTTN | c.4403G>C p.G1468A | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350062404, COSV55348730; called by muse, mutect2, varscan2
- SAG | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.39); catalogued as rs763815691, COSV68591483; called by muse, mutect2, varscan2
- SCN11A | c.2944C>T p.R982* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs145290679, COSV56569403; called by muse, mutect2, varscan2
- SCN3A | c.3973G>A p.V1325M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51817572; called by muse, mutect2, varscan2
- SERPINB13 | c.604T>A p.W202R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99500890; called by muse, mutect2, varscan2
- SLC22A25 | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV60597584; called by muse, mutect2, varscan2
- SLC27A6 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as rs1398108671, COSV52485402, COSV52485587; called by muse, mutect2, varscan2
- SLC44A5 | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63769732; called by muse, mutect2, varscan2
- SLC6A20 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62072020; called by muse, mutect2, varscan2
- SLC6A6 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as rs1267212841, COSV62651242; called by muse, mutect2, varscan2
- SLIT2 | c.3593T>G p.L1198R | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56584524; called by muse, varscan2
- TAC1 | c.205G>C p.G69R | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59987939; called by muse, mutect2, varscan2
- TAC1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747444005, COSV59986979; called by muse, mutect2, varscan2
- TBC1D4 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV100884513, COSV66490531; called by muse, mutect2, varscan2
- TBX18 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.576); catalogued as COSV63737532; called by muse, mutect2, varscan2
- TCF7L1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56401036; called by muse, mutect2, varscan2
- TEK | c.2422A>G p.K808E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66231046; called by muse, mutect2, varscan2
- TLL1 | c.1721-1G>A p.X574_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV50306681, COSV99289298; called by muse, mutect2, varscan2
- TMEM108 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as COSV58877207; called by muse, mutect2, varscan2
- TTC17 | c.2725C>T p.R909C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs747480720, COSV50013740; called by muse, mutect2, varscan2
- UGT1A6 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs751579554, COSV59394170; called by muse, mutect2, varscan2
- USH2A | c.13541G>A p.S4514N | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1012739354, COSV56403604; called by muse, mutect2, varscan2
- VAT1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs751810529, COSV55896099; called by muse, mutect2, varscan2
- WAPL | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV53933432, COSV53938019; called by muse, mutect2, varscan2
- WDR24 | c.2119G>A p.E707K (on ENST00000248142; = p.E577K on NM_032259.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV50200501; called by muse, mutect2, varscan2
- XIRP2 | c.2194G>A p.G732R (on ENST00000628543; = p.G907R on NM_152381.6) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54718915, COSV54739237; called by muse, varscan2
- XPOT | c.557C>A p.S186* | Nonsense Mutation (SNP) | VAF 41/77 reads (53%) | catalogued as COSV60346880; called by muse, varscan2
- XPOT | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60343879; called by muse, mutect2, varscan2
- XPOT | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 122/188 reads (65%) | catalogued as COSV60346903; called by muse, varscan2
- XPOT | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV60346911; called by muse, varscan2
- ZFYVE26 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61331417, COSV61333378; called by muse, mutect2
- ZMAT4 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52707472; called by muse, mutect2, varscan2
- ZNF160 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.698); catalogued as rs769856276, COSV61998962; called by muse, mutect2, varscan2
- ZNF285 | c.669T>G p.N223K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV58410070; called by mutect2, varscan2
- ZNF354B | c.822A>T p.E274D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV59366910; called by muse, mutect2, varscan2
- ZNF440 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58371813; called by muse, mutect2, varscan2
- ZNF585B | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100459289; called by muse, mutect2, varscan2
- ZNF79 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV61071466; called by muse, mutect2, varscan2
- HYDIN | c.12589G>A p.D4197N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.797); called by muse, mutect2
- NMI | c.830del p.N277Tfs*14 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- RBM11 | c.825dup p.K276* | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | called by mutect2, varscan2
- RNF148 | c.263_272del p.P88Lfs*37 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- XIRP2 | c.2193dup p.G732Rfs*4 (on ENST00000628543; = p.G907Rfs*4 on NM_152381.6) | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | called by pindel, varscan2
- AAAS | c.873C>T p.T291= | Silent (SNP) | VAF 174/258 reads (67%) | catalogued as COSV52933680; called by muse, varscan2
- ACTBL2 | c.414G>A p.Q138= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV70661526; called by muse, mutect2, varscan2
- ADAM28 | c.2073C>A p.S691= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as COSV56103038; called by muse, mutect2, varscan2
- AIRE | c.735G>A p.K245= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV52395570; called by muse, mutect2, varscan2
- AMHR2 | c.165C>T p.C55= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as COSV57686413; called by muse, mutect2, varscan2
- ANPEP | c.1959C>T p.I653= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55593281; called by muse, mutect2, varscan2
- CACNA1E | c.5001G>A p.E1667= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV62407422; called by muse, mutect2, varscan2
- CFH | c.3510C>T p.S1170= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV66411051; called by muse, mutect2, varscan2
- CSMD1 | c.924G>A p.Q308= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs774679523, COSV68231415; called by muse, mutect2
- CTNND2 | c.2628G>A p.G876= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100471378; called by muse, mutect2, varscan2
- DCDC1 | c.3360G>A p.Q1120= (on ENST00000597505 / NM_001367979.1; = p.Q227= on NM_020869.3) | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV60308962; called by muse, mutect2, varscan2
- DOCK2 | c.4464G>A p.S1488= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as rs752065132, COSV56973914; called by muse, mutect2, varscan2
- DSCAM | c.1269G>A p.P423= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs751473200, COSV68023256; called by muse, mutect2, varscan2
- DSP | c.1398C>T p.L466= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV65794247; called by muse, mutect2, varscan2
- DYSF | c.1438C>T p.L480= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV50493931; called by muse, mutect2, varscan2
- FAM168A | c.99C>T p.A33= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV50359010; called by muse, mutect2, varscan2
- FLG | c.6270C>T p.F2090= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as rs553906156, COSV64241002; called by muse, mutect2, varscan2
- GNB1L | c.180T>A p.V60= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1208098570, COSV61549126; called by muse, mutect2, varscan2
- GRIK5 | c.2478C>T p.F826= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV53477890; called by muse, mutect2, varscan2
- IFT122 | c.1092C>T p.A364= (on ENST00000348417 / NM_052989.3; = p.A305= on NM_018262.4) | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as rs71333615, COSV56205779; called by muse, mutect2, varscan2
- IGHG4 | c.840C>T p.S280= | Silent (SNP) | VAF 70/525 reads (13%) | catalogued as rs587731180; called by muse, mutect2, varscan2
- KCNIP1 | c.66C>T p.I22= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as rs754975322, COSV61079960; called by muse, mutect2, varscan2
- KDR | c.1035G>A p.G345= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV55771312; called by muse, mutect2, varscan2
- ONECUT2 | c.1350C>T p.R450= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV72153211; called by muse, mutect2, varscan2
- OR13G1 | c.105T>C p.A35= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV62944808; called by muse, mutect2
- OR8B4 | c.99G>A p.G33= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs267602759, COSV62070209; called by muse, mutect2, varscan2
- PCARE | c.615C>T p.I205= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs752130350, COSV59056308; called by muse, mutect2, varscan2
- PCDH15 | c.4983G>A p.R1661= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs867467512, COSV100902200, COSV64715566; called by muse, mutect2
- PCLO | c.9690C>T p.R3230= | Silent (SNP) | VAF 15/202 reads (7%) | catalogued as COSV61651847; called by muse, mutect2
- PHACTR2 | c.1422C>T p.R474= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV59856690; called by muse, mutect2, varscan2
- PICK1 | c.234C>T p.I78= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV63661417; called by muse, mutect2, varscan2
- PIGG | c.1827C>T p.L609= (on ENST00000453061 / NM_001127178.3; = p.L601= on NM_017733.4) | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV56319871; called by muse, mutect2, varscan2
- PIP4P2 | c.84C>T p.Y28= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV53439861; called by muse, mutect2, varscan2
- POM121L12 | c.282C>T p.S94= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1038709836, COSV68692409; called by muse, mutect2, varscan2
- RASGRP3 | c.1857C>T p.V619= (on ENST00000402538 / NM_001349975.2; = p.V618= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs758097472, COSV67823683; called by muse, mutect2, varscan2
- RNF165 | c.84G>A p.Q28= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53976161; called by muse, mutect2, varscan2
- SAFB | c.1278C>T p.F426= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV52652804; called by muse, mutect2, varscan2
- SEMA3F | c.1047C>T p.D349= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs145957797; called by muse, mutect2, varscan2
- SNX9 | c.1338C>T p.A446= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV67585300; called by muse, mutect2, varscan2
- STAB2 | c.3501G>A p.E1167= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV66343304; called by muse, mutect2, varscan2
- TRANK1 | c.4584G>A p.R1528= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57151207; called by muse, mutect2, varscan2
- TRMT44 | c.1737C>T p.P579= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV67664458; called by muse, mutect2, varscan2
- UCKL1 | c.597T>G p.G199= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV62403395; called by muse, mutect2, varscan2
- VSIG10 | c.183G>A p.S61= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs117781232; called by muse, mutect2, varscan2
- ZEB2 | c.666C>T p.R222= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs146662449; called by muse, varscan2
- HERC2P3 | n.1651G>A | RNA (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- MFRP | chr11:119345877 C>T | 5'Flank (SNP) | VAF 39/109 reads (36%) | catalogued as COSV64128896; called by muse, mutect2, varscan2
